Somatic mutation profile of tumor specimen TCGA-69-A59K-01A (aliquot TCGA-69-A59K-01A-11D-A25L-08) from TCGA case TCGA-69-A59K, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 60.5 years (22,093 days).
Specimen TCGA-69-A59K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64a87a6e-49fe-4416-8272-38833006c015.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-A59K-10A (Blood Derived Normal), aliquot TCGA-69-A59K-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a09f5eb-719e-4b40-a83f-cc609c5252c6

The open-access MAF lists 520 somatic variants for this specimen: 383 protein-altering or splice-affecting, 116 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 331, Silent 116, Nonsense Mutation 30, RNA 10, Frame Shift Del 10, Splice Site 7, Intron 7, Splice Region 3, 5'Flank 2, Frame Shift Ins 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PROC | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as rs121918146, CM920595, COSV99300890; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TYR | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61754375, CM920694, COSV54474139; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.2097G>T p.Q699H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV65316238; called by muse, mutect2, varscan2
- ABCC5 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV99657596; called by muse, mutect2, varscan2
- ACAD10 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.159); catalogued as COSV100564610; called by muse, mutect2
- ADAM11 | c.2042G>A p.G681E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.057); catalogued as rs373053731; called by muse, mutect2, varscan2
- ADAMTS19 | c.851C>A p.S284Y | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV50806546, COSV99180725; called by muse, mutect2, varscan2
- ADAMTS20 | c.749G>T p.R250M | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101240364, COSV67126686; called by muse, mutect2, varscan2
- ADCY2 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100604133; called by muse, mutect2, varscan2
- ADGRG4 | c.8741G>T p.C2914F | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as COSV54961928, COSV99795616; called by muse, mutect2, varscan2
- ADGRL3 | c.2811T>A p.S937R (on ENST00000506720 / NM_001322402.2; = p.S869R on NM_015236.6) | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.065); catalogued as COSV101547393; called by muse, mutect2, varscan2
- AGRN | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV101039080; called by muse, mutect2, varscan2
- AKR1B10 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100610257, COSV62055328; called by muse, mutect2, varscan2
- ALPK1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99455180; called by muse, mutect2, varscan2
- ALPP | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV101235189; called by muse, varscan2
- AMPH | c.1726G>T p.G576C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100343649; called by muse, mutect2, varscan2
- AMTN | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 73/291 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.677); catalogued as COSV100219854; called by muse, mutect2, varscan2
- ANAPC4 | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.353); catalogued as rs149749991; called by muse, mutect2, varscan2
- ANKEF1 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as rs1004381607, COSV65692344; called by muse, mutect2, varscan2
- ANKRD54 | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99316583; called by muse, mutect2
- ANXA9 | c.709T>C p.Y237H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1028463218, COSV100929168; called by muse, mutect2, varscan2
- ARMC5 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51658601, COSV99192838; called by muse, mutect2, varscan2
- ASAP1 | c.2571G>T p.W857C | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100727843; called by muse, mutect2, varscan2
- ASB12 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs752937556, COSV100744703; called by muse, mutect2, varscan2
- ASIC5 | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.272); catalogued as COSV101611158; called by muse, mutect2, varscan2
- ASTN2 | c.584C>A p.S195* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as COSV100530346, COSV57775494; called by muse, mutect2, varscan2
- ATP9A | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100125630; called by muse, mutect2, varscan2
- BAALC | c.373C>A p.P125T (on ENST00000297574 / NM_001364874.1; = p.P90T on NM_024812.3) | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as COSV99883875; called by muse, mutect2, varscan2
- BCL11B | c.830C>A p.S277Y (on ENST00000357195 / NM_001282237.2; = p.S206Y on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100595915; called by muse, mutect2
- BIRC6 | c.8189C>G p.T2730R | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV101428897; called by muse, mutect2, varscan2
- BMS1 | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as COSV100996826; called by muse, mutect2, varscan2
- BNC2 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV101034458, COSV66146090; called by muse, mutect2, varscan2
- BRINP3 | c.2167C>A p.L723I | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.432); catalogued as COSV66518269; called by muse, mutect2, varscan2
- BTNL8 | c.1105G>T p.V369L | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.085); catalogued as rs775692069, COSV99180581; called by muse, mutect2, varscan2
- C10orf71 | c.1990A>G p.K664E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV100110659; called by muse, mutect2, varscan2
- C19orf44 | c.388A>T p.R130* | Nonsense Mutation (SNP) | VAF 53/157 reads (34%) | catalogued as COSV99522341; called by muse, mutect2, varscan2
- C6 | c.520G>T p.G174W | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99667795; called by muse, mutect2, varscan2
- C7 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100496601, COSV57471994; called by muse, mutect2, varscan2
- CACNA1F | c.4235G>C p.C1412S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545386; called by muse, mutect2, varscan2
- CACNA1S | c.5300C>T p.P1767L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100755380; called by muse, mutect2, varscan2
- CACNA1S | c.4039G>T p.G1347W | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100755381, COSV62941322; called by muse, mutect2, varscan2
- CBWD1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 19/123 reads (15%) | catalogued as COSV100071295; called by mutect2, varscan2
- CCAR2 | c.2073G>C p.M691I | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.838); catalogued as COSV99374327; called by muse, mutect2, varscan2
- CCDC102B | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV100104903; called by muse, mutect2, varscan2
- CCDC178 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.078); catalogued as COSV100286769; called by muse, mutect2, varscan2
- CCDC183 | c.1599G>T p.K533N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV100273744; called by muse, varscan2
- CCDC190 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 92/368 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs902766374, COSV100905845, COSV63363573; called by muse, mutect2, varscan2
- CCDC39 | c.616T>A p.L206M | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as COSV99870642; called by muse, mutect2, varscan2
- CCDC81 | c.1808C>A p.A603D (on ENST00000445632 / NM_001156474.2; = p.A513D on NM_021827.4) | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV53578417, COSV99564888; called by muse, mutect2, varscan2
- CCER1 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 26/127 reads (20%) | catalogued as COSV100727163; called by muse, mutect2, varscan2
- CD96 | c.1151C>A p.S384* (on ENST00000283285 / NM_198196.3; = p.S368* on NM_005816.5) | Nonsense Mutation (SNP) | VAF 14/150 reads (9%) | catalogued as COSV99343594; called by muse, mutect2
- CDH17 | c.1551+1G>A p.X517_splice | Splice Site (SNP) | VAF 21/93 reads (23%) | catalogued as COSV99218024; called by muse, mutect2, varscan2
- CDH18 | c.791A>T p.N264I | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99938417; called by muse, mutect2, varscan2
- CDH20 | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV99406555; called by muse, mutect2, varscan2
- CEP152 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100359167, COSV57861073; called by muse, mutect2, varscan2
- CHRNG | c.164T>A p.L55Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99286144; called by muse, mutect2, varscan2
- CMPK2 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1432015408, COSV99879047; called by muse, mutect2, varscan2
- CNTRL | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV99443863; called by muse, mutect2, varscan2
- COG7 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100207820; called by muse, mutect2, varscan2
- COG8 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99650918; called by muse, mutect2, varscan2
- COL11A1 | c.5263G>T p.D1755Y | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100618047; called by muse, mutect2, varscan2
- COL1A2 | c.3361C>A p.Q1121K | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as COSV51954096; called by muse, mutect2, varscan2
- COL3A1 | c.3253C>A p.P1085T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.987); catalogued as COSV100483726; called by muse, mutect2, varscan2
- COL4A5 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100089927; called by muse, mutect2, varscan2
- CPS1 | c.3544G>T p.G1182C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV99244079; called by muse, mutect2, varscan2
- CRKL | c.238C>G p.H80D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100574207; called by muse, mutect2, varscan2
- CRYBG2 | c.4666G>T p.V1556L | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100366994; called by muse, mutect2, varscan2
- CSMD2 | c.5225G>A p.R1742H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150609588; called by mutect2, varscan2
- CSMD2 | c.5224C>A p.R1742S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99595320; called by muse, mutect2, varscan2
- CSMD2 | c.4799T>G p.L1600R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99595322; called by muse, mutect2
- CSMD3 | c.6949C>A p.P2317T (on ENST00000297405 / NM_001363185.1; = p.P2213T on NM_052900.3) | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV99847711; called by muse, mutect2, varscan2
- CSMD3 | c.6324A>T p.L2108F (on ENST00000297405 / NM_001363185.1; = p.L2004F on NM_052900.3) | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV99847714; called by muse, mutect2, varscan2
- CSMD3 | c.1612G>T p.D538Y (on ENST00000297405 / NM_001363185.1; = p.D434Y on NM_052900.3) | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52252722, COSV99847716; called by muse, mutect2, varscan2
- CSMD3 | c.1121C>A p.P374H | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.123); catalogued as COSV99847717; called by muse, mutect2, varscan2
- CSMD3 | c.178+1G>T p.X60_splice | Splice Site (SNP) | VAF 98/352 reads (28%) | catalogued as COSV52306838; called by muse, mutect2, varscan2
- CXorf66 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as COSV100983946; called by muse, mutect2, varscan2
- DAB1 | c.1730C>A p.P577H (on ENST00000371231; = p.P544H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100976649; called by muse, mutect2, varscan2
- DCT | c.1044G>T p.R348S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV100986310; called by muse, mutect2, varscan2
- DGKH | c.1596A>T p.K532N | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV99819568; called by muse, mutect2, varscan2
- DHTKD1 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV99536931; called by muse, mutect2, varscan2
- DIAPH3 | c.630G>T p.W210C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933521; called by muse, mutect2, varscan2
- DMD | c.6342G>T p.K2114N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV100822821; called by muse, mutect2, varscan2
- DMD | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99926171; called by muse, mutect2
- DMRTB1 | c.932T>C p.V311A | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV101008410; called by muse, mutect2, varscan2
- DNAH5 | c.10168G>T p.D3390Y | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99454214; called by muse, mutect2, varscan2
- DNAH5 | c.7210G>T p.D2404Y | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99454218; called by muse, mutect2, varscan2
- DOCK10 | c.2596G>T p.E866* | Nonsense Mutation (SNP) | VAF 49/214 reads (23%) | catalogued as COSV99291643; called by muse, mutect2, varscan2
- DOCK11 | c.1791A>T p.L597F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99354741; called by muse, mutect2, varscan2
- DPP6 | c.953T>C p.I318T (on ENST00000377770 / NM_001364500.2; = p.I256T on NM_001936.5) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59645550; called by muse, mutect2
- DSC1 | c.1220C>A p.T407K | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99938283; called by muse, mutect2, varscan2
- DSC2 | c.1974G>T p.M658I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99199878; called by muse, mutect2, varscan2
- DSG3 | c.1000-1G>T p.X334_splice | Splice Site (SNP) | VAF 23/69 reads (33%) | catalogued as COSV99934733; called by muse, mutect2, varscan2
- DST | c.20233A>T p.I6745F (on ENST00000361203 / NM_001374722.1; = p.I4442F on NM_015548.5) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99760016; called by muse, mutect2, varscan2
- EBF2 | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV101282285, COSV68776477; called by muse, mutect2, varscan2
- ELAVL2 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 95/247 reads (38%) | catalogued as COSV99805724, COSV99807205; called by muse, mutect2, varscan2
- ENG | c.1013C>A p.P338H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100785346; called by muse, mutect2, varscan2
- EPHA3 | c.1355G>T p.S452I | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60707172; called by muse, mutect2, varscan2
- EPHA3 | c.1552G>T p.G518W | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100348784; called by muse, mutect2, varscan2
- EPHA5 | c.2803C>A p.L935M | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.865); catalogued as COSV99901268; called by muse, mutect2, varscan2
- ERVW-1 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as COSV101423868; called by muse, mutect2
- EYS | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100677175; called by muse, mutect2, varscan2
- EYS | c.581G>T p.W194L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.373); catalogued as COSV60986518; called by muse, mutect2, varscan2
- F5 | c.3113C>A p.T1038K | Missense Mutation (SNP) | VAF 99/406 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV100889246; called by muse, mutect2, varscan2
- FAM47B | c.898C>G p.P300A | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.287); catalogued as COSV100264643, COSV61454030; called by muse, mutect2, varscan2
- FAT3 | c.10232G>T p.G3411V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV53154394; called by muse, mutect2, varscan2
- FBLN7 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.882); catalogued as rs774573945, COSV99735004; called by muse, mutect2, varscan2
- FCGR3A | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV100914717; called by muse, mutect2, varscan2
- FCRL2 | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV100830007; called by muse, mutect2, varscan2
- FGD1 | c.1497+1G>A p.X499_splice | Splice Site (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100911256; called by muse, mutect2, varscan2
- FH | c.964G>T p.V322F | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845086; called by muse, mutect2, varscan2
- FLNA | c.2403G>T p.Q801H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV100775248; called by muse, mutect2, varscan2
- FLT3 | c.1427A>T p.E476V | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV99610224; called by muse, mutect2, varscan2
- FOXK1 | c.1202G>C p.G401A | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100195836; called by muse, mutect2, varscan2
- FRMPD3 | c.1717C>T p.Q573* | Nonsense Mutation (SNP) | VAF 10/114 reads (9%) | catalogued as rs1475372242, COSV99345879; called by muse, mutect2
- GABRA1 | c.1316G>T p.W439L | Missense Mutation (SNP) | VAF 83/180 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99196282; called by muse, mutect2, varscan2
- GABRB3 | c.681A>T p.T227= | Splice Region (SNP) | VAF 33/93 reads (35%) | catalogued as COSV100161841, COSV54677094; called by muse, mutect2, varscan2
- GABRD | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.137); catalogued as COSV101059575; called by muse, mutect2, varscan2
- GATA6 | c.1717A>T p.S573C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99333475; called by muse, mutect2, varscan2
- GBE1 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV101450294; called by muse, mutect2
- GBE1 | c.1157A>T p.D386V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101450296; called by muse, mutect2, varscan2
- GC | c.1362del p.I455* | Frame Shift Del (DEL) | VAF 25/125 reads (20%) | catalogued as COSV56735771; called by mutect2, pindel, varscan2
- GDI1 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100870734; called by muse, mutect2, varscan2
- GHR | c.455C>A p.P152H | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100052020; called by muse, mutect2, varscan2
- GLIS1 | c.1450G>T p.G484W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV100390887, COSV56549039; called by muse, mutect2
- GNRHR | c.745C>T p.L249= | Splice Region (SNP) | VAF 45/341 reads (13%) | catalogued as COSV99892376; called by muse, mutect2, varscan2
- GPR141 | c.55C>A p.H19N | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100550469; called by muse, mutect2
- GRM5 | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100554542; called by muse, mutect2, varscan2
- GZMB | c.100T>A p.Y34N | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99362536; called by muse, mutect2, varscan2
- HAS2 | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392190, COSV58264318; called by muse, mutect2, varscan2
- HAUS7 | c.1047G>A p.W349* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100444316; called by muse, mutect2, varscan2
- HCK | c.1355C>A p.T452N | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV99394591; called by muse, mutect2, varscan2
- HHATL | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV99825776; called by muse, mutect2, varscan2
- HRNR | c.6068C>A p.S2023* | Nonsense Mutation (SNP) | VAF 68/2161 reads (3%) | catalogued as COSV100913939; called by muse, mutect2
- HRNR | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 114/510 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs199645117; called by muse, varscan2
- HYDIN | c.1136C>A p.S379Y | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55491428; called by muse, mutect2
- IFT52 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100887678; called by muse, mutect2, varscan2
- IGHV3-23 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782701477; called by muse, mutect2, varscan2
- IL13RA2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV99683375; called by muse, mutect2, varscan2
- IL18RAP | c.1073T>A p.V358E | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV99962416; called by muse, mutect2, varscan2
- IRX3 | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV100315413; called by muse, mutect2, varscan2
- ITGA5 | c.258C>A p.S86R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV99516966; called by muse, mutect2, varscan2
- ITSN2 | c.4448A>G p.N1483S | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs369035944; called by muse, mutect2, varscan2
- JAG1 | c.1525T>A p.F509I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99653536; called by muse, mutect2, varscan2
- JPH1 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs960918838, COSV100646776; called by muse, mutect2, varscan2
- KAT6A | c.1832A>T p.E611V | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99705897; called by muse, mutect2, varscan2
- KAZN | c.1402T>A p.C468S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV101057180; called by muse, mutect2, varscan2
- KCNN2 | c.585G>T p.L195F (on ENST00000264773; = p.L407F on NM_021614.4) | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53282720, COSV99300727; called by muse, mutect2, varscan2
- KDM4A | c.2536C>G p.Q846E | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100969659; called by muse, mutect2, varscan2
- KIDINS220 | c.4259A>T p.Q1420L | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.094); catalogued as COSV99876474; called by muse, mutect2, varscan2
- KIF21A | c.2232G>T p.R744S (on ENST00000361418 / NM_001378440.1; = p.R731S on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV100735669; called by muse, mutect2, varscan2
- KIF26A | c.1494G>T p.W498C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100181559; called by muse, mutect2, varscan2
- KIF26B | c.2377C>A p.Q793K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100833421, COSV63649190; called by muse, mutect2
- KLF8 | c.466A>T p.I156F | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as rs779134931, COSV100808425; called by muse, mutect2, varscan2
- KLHL1 | c.853C>A p.L285I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV100918151; called by muse, mutect2, varscan2
- KLHL13 | c.1083G>T p.M361I | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99452508, COSV99452929; called by muse, mutect2, varscan2
- KLHL2 | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99900353; called by muse, mutect2, varscan2
- KLHL6 | c.1353C>A p.A451= | Splice Region (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100385055, COSV58068388; called by muse, mutect2, varscan2
- KYAT3 | c.880G>C p.G294R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99556986; called by muse, mutect2, varscan2
- LAMA3 | c.5096G>T p.G1699V (on ENST00000313654 / NM_198129.4; = p.G90V on NM_000227.6) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1176451059, COSV99335826; called by muse, mutect2, varscan2
- LHB | c.358T>A p.C120S | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55484314, COSV99669269; called by muse, mutect2, varscan2
- LNX1 | c.1408G>T p.D470Y (on ENST00000263925 / NM_001126328.3; = p.D374Y on NM_032622.2) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99820618; called by muse, mutect2, varscan2
- LRP1 | c.6104G>A p.R2035Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs768348334, COSV99677229; called by muse, mutect2, varscan2
- LRP1B | c.8211G>T p.W2737C | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67234508; called by muse, mutect2, varscan2
- LRRC6 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99138600; called by muse, mutect2, varscan2
- LRRC66 | c.93A>C p.L31F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV100603106; called by mutect2, varscan2
- LTBP1 | c.2176A>T p.K726* (on ENST00000404816 / NM_206943.4; = p.K400* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100617940; called by muse, mutect2, varscan2
- MAGEB4 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV100975106; called by muse, mutect2
- MAGEC3 | c.1693G>T p.E565* | Nonsense Mutation (SNP) | VAF 28/189 reads (15%) | catalogued as COSV100025227, COSV68924260; called by muse, mutect2, varscan2
- MAMLD1 | c.2095C>A p.L699I | Missense Mutation (SNP) | VAF 35/287 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99476597; called by muse, mutect2, varscan2
- MCC | c.1537G>C p.A513P | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as COSV100203200; called by muse, mutect2, varscan2
- MCM5 | c.86C>G p.S29W | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as COSV99331977; called by muse, mutect2, varscan2
- MCM5 | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.817); catalogued as COSV99332014; called by muse, mutect2, varscan2
- MCPH1 | c.2158G>T p.G720C | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563292953, COSV100291202; called by muse, mutect2, varscan2
- MED6 | c.185A>C p.Q62P | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV99833050; called by muse, mutect2, varscan2
- MGA | c.5594A>G p.N1865S (on ENST00000219905 / NM_001164273.1; = p.N1656S on NM_001080541.2) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV99581562; called by muse, mutect2, varscan2
- MID1 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV100452719, COSV58195454; called by muse, mutect2, varscan2
- MLLT10 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as COSV100308792; called by muse, mutect2, varscan2
- MPI | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100086392; called by muse, mutect2, varscan2
- MROH8 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV99457926; called by muse, mutect2, varscan2
- MSH5 | c.1258G>T p.V420F | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100994982; called by muse, mutect2, varscan2
- MTARC2 | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100831070; called by muse, mutect2, varscan2
- MTARC2 | c.710G>T p.R237M | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100831072; called by muse, mutect2, varscan2
- MTERF3 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 32/133 reads (24%) | catalogued as COSV99750110; called by muse, mutect2, varscan2
- MTMR1 | c.1583C>T p.T528I | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV100953136, COSV100953162; called by muse, mutect2, varscan2
- MTMR10 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100076365; called by muse, mutect2, varscan2
- MYH2 | c.4703A>T p.Q1568L | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV99820981; called by muse, mutect2, varscan2
- MYH4 | c.5659G>A p.E1887K | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99702245; called by muse, mutect2, varscan2
- MYPN | c.3206G>T p.R1069L | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100590633; called by muse, mutect2, varscan2
- N4BP3 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99200822; called by muse, mutect2, varscan2
- NDUFS8 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs865986879, COSV99142086; called by muse, mutect2, varscan2
- NEB | c.673C>G p.P225A | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99428034; called by muse, mutect2, varscan2
- NEDD4 | c.2555C>T p.P852L (on ENST00000508342 / NM_001284338.1; = p.P433L on NM_006154.4) | Missense Mutation (SNP) | VAF 104/292 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100164141; called by muse, mutect2, varscan2
- NEU4 | c.640C>A p.L214I (on ENST00000391969 / NM_001167602.3; = p.L226I on NM_080741.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV100372200; called by muse, mutect2, varscan2
- NID1 | c.3422C>A p.P1141H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.355); catalogued as COSV99938333; called by muse, mutect2, varscan2
- NIM1K | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100390465; called by muse, mutect2, varscan2
- NIPBL | c.5747C>G p.T1916S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.177); catalogued as COSV99242691; called by muse, mutect2, varscan2
- NLGN3 | c.2258C>A p.P753Q (on ENST00000358741 / NM_181303.2; = p.P733Q on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.051); catalogued as COSV100705051; called by muse, mutect2, varscan2
- NPY1R | c.678T>A p.F226L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.833); catalogued as COSV99649074; called by muse, mutect2, varscan2
- NRCAM | c.2425T>C p.S809P (on ENST00000379028 / NM_001371124.1; = p.S793P on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.258); catalogued as COSV100695506; called by muse, mutect2, varscan2
- NUP210 | c.4788G>T p.Q1596H | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV99597041; called by muse, mutect2, varscan2
- OBSL1 | c.3076G>T p.G1026W | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99217499; called by muse, mutect2, varscan2
- OPRK1 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.344); catalogued as rs747565006, COSV99654383; called by muse, mutect2, varscan2
- OR10A7 | c.769C>A p.L257M | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.258); catalogued as COSV100406491, COSV100406633; called by muse, mutect2, varscan2
- OR10Q1 | c.519del p.C173Wfs*35 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as COSV57469769; called by mutect2, pindel, varscan2
- OR11G2 | c.649T>A p.C217S | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100640051; called by muse, mutect2, varscan2
- OR11L1 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100869453, COSV63315963; called by muse, mutect2
- OR2T3 | c.275C>G p.T92S | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV100613417; called by muse, mutect2, varscan2
- OR2W3 | c.787G>T p.G263* | Nonsense Mutation (SNP) | VAF 39/154 reads (25%) | catalogued as COSV100831850; called by muse, mutect2, varscan2
- OR2W3 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as COSV64455951, COSV64456750; called by muse, mutect2, varscan2
- OR51G2 | c.256G>C p.V86L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV100432241; called by muse, mutect2, varscan2
- OR5D13 | c.875A>C p.Y292S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100687065; called by muse, varscan2
- OR5D13 | c.919G>T p.V307F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV100687002, COSV100687067; called by muse, varscan2
- OR5M3 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs769332657, COSV56566646; called by muse, mutect2, varscan2
- OR7A10 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV99932528; called by muse, mutect2
- OR8J1 | c.396C>G p.Y132* | Nonsense Mutation (SNP) | VAF 36/145 reads (25%) | catalogued as COSV100275208, COSV57318143; called by muse, mutect2, varscan2
- OR8U1 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as COSV100164131; called by muse, mutect2
- OTOF | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99718985; called by muse, mutect2, varscan2
- OTUD6A | c.695C>A p.P232H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100611086, COSV57972890; called by muse, mutect2, varscan2
- OVCH1 | c.932G>T p.R311M | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.501); catalogued as COSV100549223; called by muse, mutect2, varscan2
- PADI3 | c.911C>A p.P304Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.725); catalogued as COSV64934437; called by muse, mutect2, varscan2
- PAX1 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68271936, COSV68273608; called by muse, mutect2, varscan2
- PCDHA4 | c.719C>G p.P240R | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100793750, COSV63543369; called by muse, mutect2, varscan2
- PCDHB13 | c.1368C>A p.Y456* | Nonsense Mutation (SNP) | VAF 83/207 reads (40%) | catalogued as COSV99507845; called by muse, mutect2, varscan2
- PCDHB3 | c.1744C>G p.P582A | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.011); catalogued as COSV50604835, COSV99166624; called by muse, mutect2, varscan2
- PCDHB4 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV52019582; called by muse, mutect2, varscan2
- PCDHGB3 | c.368T>A p.I123N | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99546993; called by muse, mutect2, varscan2
- PDE4B | c.1505A>T p.Q502L | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100305041; called by muse, mutect2, varscan2
- PDE6B | c.1228T>A p.F410I | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99728393; called by muse, mutect2, varscan2
- PGR | c.1954G>C p.D652H | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV99679121; called by muse, mutect2, varscan2
- PHEX | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101040029; called by muse, mutect2, varscan2
- PIGO | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99956960; called by muse, mutect2, varscan2
- PIP4K2C | c.877G>T p.G293C | Missense Mutation (SNP) | VAF 100/361 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100533800; called by muse, mutect2, varscan2
- PKD1L1 | c.737G>T p.S246I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99221381; called by muse, mutect2, varscan2
- PLCL1 | c.2865G>T p.E955D | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.644); catalogued as rs1489067403, COSV101407293; called by muse, mutect2, varscan2
- PLEKHA5 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV100164755; called by muse, mutect2, varscan2
- PLEKHA8 | c.884G>T p.C295F | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99322241; called by muse, mutect2, varscan2
- PLEKHG3 | c.1265C>T p.S422F (on ENST00000394691; = p.S478F on NM_001308147.2) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.367); catalogued as COSV55979144; called by muse, mutect2, varscan2
- PLPPR4 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs528165502, COSV100926936; called by muse, mutect2, varscan2
- PLXND1 | c.5503G>A p.V1835M | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60711113; called by muse, mutect2, varscan2
- PMS1 | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100575792; called by muse, mutect2, varscan2
- PNOC | c.371A>T p.K124M | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100108410; called by muse, mutect2
- POLD3 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs777292433, COSV55242934; called by muse, mutect2, varscan2
- POM121L12 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.798); catalogued as rs746175412, COSV68692799; called by muse, mutect2, varscan2
- PORCN | c.15C>A p.S5R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV100400565; called by muse, mutect2, varscan2
- POTEH | c.440G>T p.R147M | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs775126936, COSV100625199, COSV100625241, COSV58885178; called by muse, mutect2, varscan2
- POU3F4 | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.325); catalogued as COSV100937252; called by muse, mutect2, varscan2
- PPARD | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs772540082, COSV100283344; called by muse, mutect2, varscan2
- PRDM11 | c.412G>T p.G138C (on ENST00000530656 / NM_001359633.1; = p.G104C on NM_001256695.1) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99771109; called by muse, mutect2, varscan2
- PRNP | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV101057388; called by muse, mutect2, varscan2
- PRSS35 | c.953A>T p.D318V | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV100864153; called by muse, mutect2, varscan2
- PTGS1 | c.578C>A p.T193N | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99793549; called by muse, mutect2, varscan2
- PTPN6 | c.594del p.I199Lfs*20 | Frame Shift Del (DEL) | VAF 30/164 reads (18%) | catalogued as COSV100017117; called by mutect2, pindel, varscan2
- PTPRB | c.5857T>G p.Y1953D | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99718972; called by muse, mutect2, varscan2
- PTPRB | c.4482G>T p.E1494D | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99718976; called by muse, mutect2, varscan2
- PTPRH | c.2696C>G p.T899R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99671459; called by muse, mutect2, varscan2
- PTPRT | c.2621T>A p.L874* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as COSV100630485; called by muse, mutect2, varscan2
- PTPRT | c.1400C>A p.P467H | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100630417; called by muse, mutect2, varscan2
- PTPRZ1 | c.4747G>T p.A1583S | Missense Mutation (SNP) | VAF 106/345 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV101100850, COSV66430653; called by muse, mutect2, varscan2
- RABIF | c.144G>T p.M48I | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.654); catalogued as rs1428413641, COSV100936375; called by muse, mutect2, varscan2
- RARB | c.412A>G p.N138D (on ENST00000383772 / NM_001290216.2; = p.N131D on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100412880; called by muse, mutect2, varscan2
- RASGRF1 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101369755, COSV69183544; called by muse, mutect2, varscan2
- RCOR3 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV100879693; called by muse, mutect2, varscan2
- RFX2 | c.1916A>T p.H639L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100353989; called by muse, mutect2, varscan2
- RGS7 | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100470954, COSV58556981; called by muse, mutect2, varscan2
- RHOXF2B | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.983); catalogued as COSV101003979; called by mutect2, varscan2
- RNASE12 | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV100250625; called by muse, mutect2, varscan2
- RNF215 | c.430-1G>A p.X144_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99306723; called by muse, varscan2
- ROBO2 | c.142A>C p.T48P | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV100169946, COSV59899071, COSV59933610; called by muse, mutect2, varscan2
- RP1 | c.2756G>T p.W919L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779290365, COSV99608869; called by muse, mutect2, varscan2
- RP1L1 | c.2735G>T p.S912I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.406); catalogued as COSV101223631, COSV66751685; called by muse, mutect2, varscan2
- RP1L1 | c.2063G>T p.R688M | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV101223633; called by muse, mutect2, varscan2
- RPL26 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV99549549; called by muse, mutect2, varscan2
- RRAD | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234213; called by muse, mutect2, varscan2
- RSPO1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs377526889; called by muse, mutect2, varscan2
- RUBCN | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs771449989, COSV99583046; called by muse, mutect2, varscan2
- RUFY3 | c.540G>T p.M180I | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99886921, COSV99887938; called by muse, mutect2, varscan2
- RUSC1 | c.1618G>T p.A540S (on ENST00000368352 / NM_001105203.2; = p.A71S on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV99430292; called by muse, mutect2, varscan2
- RXFP1 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV100314205; called by muse, mutect2, varscan2
- RYR3 | c.9486G>C p.K3162N (on ENST00000389232; = p.K3163N on NM_001036.6) | Missense Mutation (SNP) | VAF 85/251 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs1356421512, COSV101214596; called by muse, mutect2, varscan2
- SAGE1 | c.742A>C p.T248P | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV100187920; called by muse, mutect2, varscan2
- SATL1 | c.1361C>T p.A454V (on ENST00000395409; = p.S627= on NM_001012980.2) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1161601382, COSV100261110; called by muse, mutect2
- SCD5 | c.296A>T p.H99L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99262695; called by muse, mutect2, varscan2
- SCN1A | c.2970G>T p.L990F (on ENST00000303395 / NM_001202435.3; = p.L979F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM087897, COSV100322146; called by muse, mutect2, varscan2
- SECISBP2 | c.1479G>C p.E493D | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.054); catalogued as COSV60530071; called by muse, mutect2, varscan2
- SELP | c.1737G>C p.E579D | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.029); catalogued as COSV99741142; called by muse, mutect2, varscan2
- SEMA5B | c.2924G>T p.S975I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99533201; called by muse, mutect2, varscan2
- SENP2 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99958180; called by muse, mutect2, varscan2
- SERPINB3 | c.1166C>A p.S389Y | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52192870, COSV99380237; called by muse, mutect2, varscan2
- SGO2 | c.3560G>T p.S1187I | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV100764803; called by muse, mutect2, varscan2
- SH3RF2 | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100768035; called by muse, mutect2, varscan2
- SHANK2 | c.2990G>A p.S997N | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs781966690, COSV99576083; called by muse, mutect2, varscan2
- SHROOM4 | c.2615G>T p.C872F | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as COSV56792912, COSV56799196; called by muse, mutect2, varscan2
- SI | c.4964G>A p.R1655Q | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as rs752540924, COSV100017187; called by muse, mutect2, varscan2
- SLAMF7 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.257); catalogued as COSV100833369; called by muse, mutect2, varscan2
- SLC13A1 | c.867C>A p.F289L | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV52010182, COSV99521475; called by muse, mutect2, varscan2
- SLC23A3 | c.1414C>T p.R472W (on ENST00000409878 / NM_001144889.2; = p.R355W on NM_144712.5) | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs200248868, COSV55407204; called by muse, mutect2, varscan2
- SLC24A2 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99647465; called by muse, mutect2, varscan2
- SLC25A13 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.489); catalogued as COSV99674201; called by muse, mutect2, varscan2
- SLC35G3 | c.445C>A p.L149I | Missense Mutation (SNP) | VAF 82/233 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as COSV99269247; called by muse, mutect2, varscan2
- SLC38A1 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101284284; called by muse, mutect2, varscan2
- SLC5A7 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99887250; called by muse, mutect2, varscan2
- SLITRK3 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV99580179; called by muse, mutect2, varscan2
- SP140L | c.1046G>T p.R349I | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV99707691; called by muse, mutect2, varscan2
- SPTA1 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 81/317 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100934980; called by muse, mutect2, varscan2
- SPTAN1 | c.3238G>T p.G1080C | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100824020; called by muse, mutect2, varscan2
- SPTBN1 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs750448290, COSV100443412; called by muse, mutect2, varscan2
- SRP72 | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV100714381; called by muse, mutect2, varscan2
- SRP72 | c.983C>G p.A328G | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as COSV100714382; called by muse, mutect2, varscan2
- SRPRA | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as COSV99703073; called by muse, mutect2, varscan2
- STARD13 | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99716385; called by muse, mutect2, varscan2
- STK26 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV100688890; called by muse, mutect2, varscan2
- STK26 | c.399C>A p.D133E | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV100688618, COSV100688891; called by muse, mutect2, varscan2
- SYTL2 | c.2191G>T p.G731W (on ENST00000528231 / NM_001162951.2; = p.G707W on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100314997; called by muse, mutect2, varscan2
- SZT2 | c.427A>T p.I143F | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.076); catalogued as COSV100161862; called by muse, mutect2, varscan2
- TAF1 | c.1993G>T p.E665* (on ENST00000373790 / NM_138923.4; = p.E686* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/181 reads (15%) | catalogued as COSV52115987, COSV99337018; called by muse, mutect2, varscan2
- TAF1 | c.2963G>A p.R988H (on ENST00000373790 / NM_138923.4; = p.R1009H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52107436; called by muse, mutect2, varscan2
- TAF1 | c.3533G>C p.R1178P (on ENST00000373790 / NM_138923.4; = p.R1199P on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99335769, COSV99337030; called by muse, mutect2, varscan2
- TAF1L | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.969); catalogued as COSV99645414; called by muse, mutect2, varscan2
- TAS2R31 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101115616; called by muse, mutect2
- TBC1D25 | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100952235; called by muse, mutect2, varscan2
- TBR1 | c.587A>T p.Q196L | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.932); catalogued as COSV101271545; called by muse, mutect2, varscan2
- TCEANC | c.381C>G p.D127E (on ENST00000380600 / NM_001297563.2; = p.D157E on NM_152634.4) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100124623, COSV100124879; called by muse, mutect2, varscan2
- TCN1 | c.885G>T p.M295I | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV99953462; called by muse, mutect2, varscan2
- THOC2 | c.3365A>C p.N1122T | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55555001; called by muse, mutect2, varscan2
- THSD7B | c.3436G>C p.D1146H (on ENST00000272643; = p.D1144H on NM_001316349.2) | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV55664515, COSV55687339; called by muse, mutect2, varscan2
- TLR4 | c.1055C>T p.S352F (on ENST00000355622 / NM_138554.5; = p.S312F on NM_003266.4) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV62923597, COSV62923701; called by muse, mutect2, varscan2
- TMEM45A | c.191-1G>T p.X64_splice | Splice Site (SNP) | VAF 19/40 reads (48%) | catalogued as COSV100058679; called by muse, mutect2
- TNN | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99513036; called by muse, mutect2, varscan2
- TPP2 | c.3067G>T p.E1023* | Nonsense Mutation (SNP) | VAF 38/104 reads (37%) | catalogued as COSV101060439; called by muse, mutect2, varscan2
- TPR | c.557A>G p.E186G | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100824250; called by muse, mutect2, varscan2
- TRIP12 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as COSV52274366; called by muse, mutect2, varscan2
- TRPC4 | c.310A>T p.I104F | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58997000; called by muse, mutect2, varscan2
- TSKS | c.840G>T p.Q280H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.471); catalogued as COSV99882926; called by muse, mutect2, varscan2
- TSN | c.377A>T p.E126V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV67605107; called by muse, mutect2, varscan2
- TSPOAP1 | c.2446G>T p.E816* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99272735; called by muse, mutect2, varscan2
- TTN | c.59427T>A p.S19809R (on ENST00000591111; = p.S12385R on NM_003319.4) | Missense Mutation (SNP) | VAF 32/125 reads (26%) | PolyPhen possibly damaging (0.885); catalogued as COSV100630194; called by muse, mutect2, varscan2
- TTN | c.18565G>T p.G6189C (on ENST00000591111; = p.G5262C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | PolyPhen probably damaging (1); catalogued as COSV100630196; called by muse, mutect2, varscan2
- TTN | c.18427G>T p.E6143* (on ENST00000591111; = p.E5216* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100620406, COSV100630197; called by muse, mutect2, varscan2
- TYR | c.168G>C p.Q56H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as CM090085, COSV99635337; called by muse, mutect2, varscan2
- UBN2 | c.561+1G>T p.X187_splice | Splice Site (SNP) | VAF 77/204 reads (38%) | catalogued as COSV56037113, COSV99944476; called by muse, mutect2, varscan2
- UCK2 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV100903048; called by muse, mutect2, varscan2
- UNC13C | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs1003162998, COSV99520569, COSV99522995; called by muse, mutect2
- UNC5D | c.871T>A p.C291S | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54845240, COSV99778786; called by muse, mutect2, varscan2
- URB2 | c.1610T>A p.L537Q | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99271905; called by muse, mutect2, varscan2
- USP33 | c.1712A>T p.D571V | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100657239; called by muse, mutect2
- USP9X | c.3231C>A p.D1077E | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100200104; called by muse, mutect2, varscan2
- VASH1 | c.745C>A p.R249S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV99388174; called by muse, mutect2
- VPS13B | c.7205A>T p.K2402I | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV100663666; called by muse, mutect2, varscan2
- VWA3A | c.2263A>T p.R755W | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100241321; called by muse, mutect2, varscan2
- VWCE | c.1825G>T p.D609Y | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100076153; called by muse, mutect2, varscan2
- WAS | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100939537; called by muse, mutect2, varscan2
- WASL | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.551); catalogued as rs371192595; called by muse, mutect2
- WIPF2 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 48/536 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs368672904, COSV100063935; called by muse, mutect2
- WWC3 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as COSV101081823; called by muse, mutect2, varscan2
- XCR1 | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100499477; called by muse, mutect2
- XPO4 | c.877C>A p.Q293K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99689174; called by muse, mutect2, varscan2
- YLPM1 | c.3425G>T p.R1142M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV99461365; called by muse, mutect2, varscan2
- ZBBX | c.745T>A p.C249S | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100284963; called by muse, mutect2, varscan2
- ZBTB7B | c.1526G>T p.G509V (on ENST00000292176; = p.G543V on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99421548; called by muse, mutect2, varscan2
- ZCWPW2 | c.336G>T p.W112C | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101075302; called by muse, mutect2, varscan2
- ZFR | c.2713G>T p.A905S | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV54050036; called by muse, mutect2
- ZNF117 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99276095; called by muse, mutect2, varscan2
- ZNF174 | c.969G>C p.K323N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as rs1362288624, COSV99237729; called by muse, mutect2, varscan2
- ZNF208 | c.2572G>T p.E858* | Nonsense Mutation (SNP) | VAF 34/120 reads (28%) | catalogued as COSV101237164, COSV101237208, COSV101237273; called by muse, mutect2, varscan2
- ZNF254 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV100741788; called by muse, mutect2
- ZNF485 | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100700293; called by muse, mutect2, varscan2
- ZNF607 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0.015); catalogued as rs144365488; called by muse, mutect2, varscan2
- ZNF609 | c.1759G>T p.G587C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV100441817; called by muse, mutect2, varscan2
- ZNF804B | c.638C>A p.A213E | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs746882193, COSV100306224; called by muse, mutect2, varscan2
- ZNF875 | c.1960C>T p.Q654* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100183553; called by muse, mutect2, varscan2
- A2ML1 | c.1620dup p.P541Sfs*8 | Frame Shift Ins (INS) | VAF 29/181 reads (16%) | called by mutect2, pindel, varscan2
- CDH17 | c.2038del p.L680Sfs*64 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- CFAP74 | c.4645C>A p.P1549T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- GAB3 | c.1563_1575del p.A522Qfs*6 | Frame Shift Del (DEL) | VAF 30/267 reads (11%) | called by mutect2, pindel
- IGHV4-28 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IL1RAPL1 | c.73del p.R25Efs*50 | Frame Shift Del (DEL) | VAF 18/99 reads (18%) | called by mutect2, pindel, varscan2
- ITGA2B | c.1684_1686delinsT p.T562Yfs*24 | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | called by pindel, varscan2*
- KCNQ5 | c.959del p.L320Qfs*33 | Frame Shift Del (DEL) | VAF 72/263 reads (27%) | called by mutect2, pindel, varscan2
- MYO19 | c.770A>T p.E257V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PCDHGA3 | c.2350_2351del p.S784Lfs*2 | Frame Shift Del (DEL) | VAF 60/212 reads (28%) | called by pindel, varscan2
- POM121C | c.2146G>A p.E716K (on ENST00000607367; = p.E474K on NM_001099415.3) | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- SYNE4 | c.305del p.L102Qfs*57 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- ZNF75D | c.586_587insT p.Q196Lfs*5 | Frame Shift Ins (INS) | VAF 20/160 reads (13%) | called by mutect2, pindel*, varscan2
- ABCG2 | c.1725A>T p.R575= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV99420186; called by muse, mutect2, varscan2
- ADAMTS14 | c.2403C>A p.P801= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100941713, COSV100941865; called by muse, mutect2, varscan2
- AMPD1 | c.891G>A p.L297= | Silent (SNP) | VAF 44/222 reads (20%) | catalogued as COSV100815241; called by muse, mutect2, varscan2
- AMPH | c.1725G>A p.P575= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100343652; called by muse, mutect2, varscan2
- ARMCX2 | c.429C>A p.P143= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV57530802; called by muse, mutect2, varscan2
- BARD1 | c.876G>A p.K292= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as rs1449269582, COSV99639873; called by muse, mutect2, varscan2
- BAZ1B | c.3792G>A p.E1264= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as COSV100290147; called by muse, mutect2, varscan2
- BECN1 | c.75G>A p.L25= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV64120737; called by muse, mutect2, varscan2
- BET1 | c.228A>T p.G76= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99747426; called by muse, mutect2, varscan2
- BPIFB6 | c.1011C>A p.T337= | Silent (SNP) | VAF 28/176 reads (16%) | catalogued as COSV100848556; called by muse, mutect2, varscan2
- BTBD7 | c.1833G>T p.T611= | Silent (SNP) | VAF 68/252 reads (27%) | catalogued as COSV100598192, COSV58285665; called by muse, mutect2, varscan2
- C10orf71 | c.1752T>G p.S584= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs767625364, COSV100110657; called by muse, mutect2, varscan2
- CA6 | c.156A>G p.L52= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV101077701; called by muse, mutect2
- CACNA1B | c.6681G>A p.R2227= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- CADPS | c.2361A>T p.R787= | Silent (SNP) | VAF 7/136 reads (5%) | catalogued as COSV99340931; called by muse, mutect2
- CAND1 | c.96G>T p.T32= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as COSV101604391, COSV73338875; called by muse, mutect2, varscan2
- CCDC40 | c.1791C>T p.L597= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100884325; called by muse, mutect2, varscan2
- CCM2 | c.570G>T p.V190= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV99348116; called by muse, mutect2, varscan2
- CCNB3 | c.4044C>T p.F1348= | Silent (SNP) | VAF 89/316 reads (28%) | catalogued as COSV99329880; called by muse, mutect2, varscan2
- CENPI | c.432G>T p.V144= | Silent (SNP) | VAF 75/532 reads (14%) | catalogued as COSV99515831; called by muse, mutect2, varscan2
- CFP | c.912C>T p.H304= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99901676; called by muse, mutect2, varscan2
- CHTOP | c.495G>C p.G165= | Silent (SNP) | VAF 34/264 reads (13%) | catalogued as COSV100904730; called by muse, mutect2, varscan2
- CNGA2 | c.633G>T p.L211= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV100323954, COSV61703505; called by muse, mutect2, varscan2
- COL6A3 | c.4491C>A p.A1497= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99800695; called by muse, mutect2, varscan2
- COPS6 | c.513C>T p.V171= | Silent (SNP) | VAF 95/241 reads (39%) | catalogued as COSV100385165; called by muse, mutect2, varscan2
- CPB1 | c.441C>T p.T147= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as rs1474677780, COSV99294547; called by muse, mutect2
- CRYBG1 | c.1446G>A p.A482= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100954625; called by mutect2, varscan2
- CTAG2 | c.579A>G p.G193= | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as COSV99909201; called by muse, mutect2, varscan2
- CTSK | c.537G>T p.G179= | Silent (SNP) | VAF 59/231 reads (26%) | catalogued as COSV99648973; called by muse, mutect2, varscan2
- CXXC1 | c.798C>G p.V266= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV53276423, COSV99497249; called by muse, mutect2, varscan2
- CYP4F2 | c.6C>A p.S2= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV50001470; called by muse, mutect2, varscan2
- DCAF4L2 | c.1098G>T p.V366= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV100151287, COSV60476751; called by muse, mutect2, varscan2
- DNAH11 | c.8418G>A p.V2806= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100180884; called by muse, mutect2, varscan2
- DNAI1 | c.862C>A p.R288= | Silent (SNP) | VAF 48/250 reads (19%) | catalogued as COSV99647173; called by muse, mutect2, varscan2
- DOCK2 | c.2973C>A p.A991= | Silent (SNP) | VAF 93/203 reads (46%) | catalogued as COSV99915443; called by muse, mutect2, varscan2
- DTX1 | c.309G>T p.P103= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs1215347941, COSV57495854, COSV99986568; called by muse, mutect2, varscan2
- EHBP1L1 | c.4254C>T p.L1418= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV58571858; called by muse, mutect2
- EPHB6 | c.1518G>T p.T506= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as COSV100844441; called by muse, mutect2, varscan2
- ERBB4 | c.60C>A p.V20= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as rs1276258041, COSV99632905; called by muse, mutect2, varscan2
- FLNC | c.4932C>T p.S1644= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV57956029; called by muse, mutect2, varscan2
- FLRT2 | c.90G>T p.V30= | Silent (SNP) | VAF 40/148 reads (27%) | catalogued as COSV100421033; called by muse, mutect2, varscan2
- FMN2 | c.2019C>A p.A673= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV100147119; called by muse, mutect2, varscan2
- FNDC1 | c.4875G>T p.P1625= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs368034028, COSV99796866; called by muse, mutect2, varscan2
- FRMD7 | c.1665C>A p.A555= | Silent (SNP) | VAF 47/286 reads (16%) | catalogued as COSV100049312; called by muse, mutect2, varscan2
- FRMPD3 | c.825T>C p.R275= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99347094; called by muse, mutect2, varscan2
- FSIP2 | c.20130A>G p.K6710= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV100556542; called by muse, mutect2, varscan2
- GAD1 | c.1083T>C p.D361= | Silent (SNP) | VAF 66/285 reads (23%) | catalogued as COSV100713934; called by muse, mutect2, varscan2
- GALNT13 | c.1104G>T p.L368= | Silent (SNP) | VAF 54/226 reads (24%) | catalogued as COSV101221769; called by muse, mutect2, varscan2
- GHSR | c.516C>T p.F172= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV99577256; called by muse, mutect2, varscan2
- GJB2 | c.549C>A p.S183= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV101241515; called by muse, mutect2, varscan2
- GLRA1 | c.609C>A p.A203= | Silent (SNP) | VAF 73/163 reads (45%) | catalogued as COSV99199685; called by muse, mutect2, varscan2
- GPIHBP1 | c.312C>T p.T104= | Silent (SNP) | VAF 39/138 reads (28%) | catalogued as COSV100427402; called by muse, mutect2, varscan2
- GPR141 | c.54C>A p.P18= | Silent (SNP) | VAF 30/308 reads (10%) | catalogued as COSV100550468; called by muse, mutect2
- GPR25 | c.795C>A p.A265= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100421790; called by muse, mutect2, varscan2
- GRIK5 | c.825C>A p.P275= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV99491369; called by muse, mutect2, varscan2
- GZMB | c.99C>A p.P33= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as COSV99362538; called by muse, mutect2, varscan2
- HGF | c.639C>A p.T213= | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as COSV99738517; called by muse, mutect2, varscan2
- HOXA6 | c.423G>A p.Q141= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as COSV99762453, COSV99762499; called by muse, mutect2
- IGHV4-28 | c.186G>T p.G62= | Silent (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.270G>T p.G90= | Silent (SNP) | VAF 63/231 reads (27%) | called by muse, mutect2, varscan2
- IKZF1 | c.507G>T p.G169= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100498752, COSV58785544; called by muse, mutect2, varscan2
- INHBA | c.1260G>A p.V420= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV99638392; called by muse, mutect2, varscan2
- ITGA5 | c.939C>A p.S313= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as COSV99516963; called by muse, mutect2, varscan2
- ITLN2 | c.954G>A p.A318= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as rs774298930, COSV63537759; called by muse, mutect2
- JAK3 | c.2889C>G p.V963= | Silent (SNP) | VAF 28/153 reads (18%) | catalogued as COSV101513028; called by muse, mutect2, varscan2
- KRT12 | c.732G>T p.L244= | Silent (SNP) | VAF 54/342 reads (16%) | catalogued as COSV52430216; called by muse, mutect2, varscan2
- KRT84 | c.468C>G p.P156= | Silent (SNP) | VAF 44/301 reads (15%) | catalogued as COSV99231053; called by muse, mutect2, varscan2
- KRTAP11-1 | c.120C>A p.I40= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as COSV100190835; called by muse, mutect2, varscan2
- LRIT2 | c.651C>T p.S217= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100259376; called by muse, mutect2, varscan2
- LRRC7 | c.4119C>A p.S1373= (on ENST00000651989 / NM_001370785.2; = p.S1293= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 53/183 reads (29%) | catalogued as COSV99229776; called by muse, mutect2, varscan2
- LRRIQ3 | c.1527C>A p.S509= | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as COSV100598683, COSV63043353; called by muse, mutect2, varscan2
- LRRN2 | c.210C>G p.G70= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV100912970; called by muse, mutect2, varscan2
- LTBP1 | c.912C>G p.T304= | Silent (SNP) | VAF 46/195 reads (24%) | catalogued as COSV100617939, COSV63184566; called by muse, mutect2, varscan2
- LYST | c.4278G>A p.L1426= | Silent (SNP) | VAF 76/298 reads (26%) | catalogued as COSV101090300; called by muse, mutect2, varscan2
- MARVELD3 | c.840C>G p.L280= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV99194872; called by muse, mutect2, varscan2
- OPHN1 | c.1857G>T p.P619= | Silent (SNP) | VAF 51/203 reads (25%) | catalogued as COSV100830769; called by muse, mutect2, varscan2
- OR13C8 | c.453T>G p.T151= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV100623024; called by muse, mutect2, varscan2
- OR13F1 | c.867C>A p.I289= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100594855; called by muse, mutect2, varscan2
- OR2T4 | c.135C>A p.I45= | Silent (SNP) | VAF 28/183 reads (15%) | catalogued as COSV100822625, COSV63544536; called by muse, mutect2, varscan2
- OR6B3 | c.786C>A p.P262= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as COSV100097666; called by muse, mutect2, varscan2
- PCDHB3 | c.639C>A p.T213= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as COSV99166615; called by muse, mutect2, varscan2
- PHYHIP | c.708C>A p.I236= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100395147, COSV58688368; called by muse, mutect2, varscan2
- PIK3CG | c.454C>A p.R152= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV63250430; called by muse, mutect2
- PITPNM1 | c.2673G>A p.E891= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV99653633; called by muse, mutect2, varscan2
- PKHD1 | c.5838C>T p.V1946= | Silent (SNP) | VAF 29/174 reads (17%) | catalogued as rs769415024, COSV100584574, COSV61863642; called by muse, mutect2, varscan2
- PKP1 | c.249C>A p.T83= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99825707; called by muse, mutect2, varscan2
- PTCHD1 | c.543G>A p.K181= | Silent (SNP) | VAF 24/174 reads (14%) | catalogued as rs1175938564, COSV65061201; called by muse, mutect2, varscan2
- SCN2A | c.5551C>A p.R1851= | Silent (SNP) | VAF 52/184 reads (28%) | catalogued as COSV51854555, COSV99333512; called by muse, mutect2, varscan2
- SEC61A1 | c.951G>T p.L317= | Silent (SNP) | VAF 26/220 reads (12%) | catalogued as rs138437267, COSV99685028; called by muse, mutect2, varscan2
- SGCZ | c.274C>A p.R92= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as COSV66020833, COSV66053884; called by muse, mutect2, varscan2
- SHANK1 | c.3510C>A p.R1170= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99522059; called by muse, mutect2, varscan2
- SLC22A10 | c.1431G>A p.R477= | Silent (SNP) | VAF 62/220 reads (28%) | catalogued as COSV60422051; called by muse, varscan2
- SLC25A37 | c.756G>A p.T252= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99264216; called by muse, mutect2
- SLC6A7 | c.1539C>A p.L513= | Silent (SNP) | VAF 43/84 reads (51%) | catalogued as COSV100046562; called by muse, mutect2, varscan2
- SLX4 | c.1944C>T p.G648= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs149315267; called by mutect2, varscan2
- SMC1A | c.2646G>A p.S882= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as rs1193658492, COSV59127805; ClinVar: likely benign; called by muse, mutect2, varscan2
- SORCS1 | c.3327G>T p.V1109= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV53848168; called by muse, mutect2, varscan2
- SPTBN2 | c.5397G>A p.A1799= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs769209192, COSV100020506; called by muse, mutect2, varscan2
- SULT1C3 | c.27C>A p.P9= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as rs1295523788, COSV61252288; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1833C>T p.I611= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- SVIL | c.4902G>A p.E1634= (on ENST00000355867 / NM_021738.3; = p.E1208= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100881542; called by muse, mutect2, varscan2
- TBC1D8 | c.453C>T p.F151= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs897230514, COSV65209753; called by muse, mutect2
- TBX3 | c.70C>A p.R24= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV57470505, COSV99984115; called by muse, mutect2, varscan2
- TENT4B | c.855C>G p.L285= (on ENST00000561678 / NM_001365323.2; = p.L270= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/154 reads (18%) | catalogued as COSV100666177; called by muse, mutect2, varscan2
- TMPRSS7 | c.2322C>A p.L774= (on ENST00000452346; = p.L648= on NM_001042575.2) | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV101340181; called by muse, mutect2, varscan2
- TNN | c.1611G>T p.L537= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV99513034; called by muse, mutect2, varscan2
- TRAPPC5 | c.426C>T p.F142= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100365443, COSV58040112; called by muse, mutect2, varscan2
- TRIM58 | c.1122G>T p.T374= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as rs765211101, COSV100825294, COSV63572147; called by muse, mutect2, varscan2
- TTC29 | c.21G>T p.L7= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100284585; called by muse, mutect2, varscan2
- TTN | c.36312C>A p.I12104= (on ENST00000591111; = p.I4680= on NM_003319.4) | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV100630195; called by muse, mutect2, varscan2
- ULK1 | c.1086G>T p.A362= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100417281; called by muse, mutect2, varscan2
- WNT3A | c.120C>T p.I40= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99470178; called by muse, mutect2, varscan2
- XCR1 | c.132C>A p.L44= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV100499479; called by muse, mutect2
- ZRANB2 | c.162G>A p.K54= | Silent (SNP) | VAF 34/224 reads (15%) | catalogued as COSV99639800; called by muse, mutect2, varscan2
- ZSCAN31 | c.510C>T p.C170= | Silent (SNP) | VAF 24/167 reads (14%) | catalogued as COSV100717150; called by muse, mutect2, varscan2
- ZWINT | c.744G>A p.E248= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV100571563; called by muse, mutect2, varscan2
- AC004080.3 | c.11-4529C>A | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99385695; called by muse, mutect2, varscan2
- AC004080.3 | c.11-4530C>A | Intron (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99385697; called by muse, mutect2, varscan2
- AC024940.1 | n.3883C>A | RNA (SNP) | VAF 12/42 reads (29%) | catalogued as rs777204359; called by muse, mutect2
- AL353804.4 | chrX:73821630 C>A | 3'Flank (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500250 G>C | 5'Flank (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- C20orf197 | n.310G>T | RNA (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.41C>A | RNA (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.427C>T | RNA (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- COLCA2 | chr11:111296191 C>A | 5'Flank (SNP) | VAF 26/117 reads (22%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+11529G>T | Intron (SNP) | VAF 34/82 reads (41%) | catalogued as COSV100456909; called by muse, mutect2, varscan2
- DST | c.4296+4390T>A | Intron (SNP) | VAF 27/76 reads (36%) | catalogued as COSV99760020; called by muse, mutect2, varscan2
- FBXL13 | c.496-5576G>T | Intron (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100502117; called by muse, mutect2, varscan2
- FOLH1B | n.1041G>C | RNA (SNP) | VAF 29/173 reads (17%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85881A>G | Intron (SNP) | VAF 29/235 reads (12%) | catalogued as rs190435914; called by muse, mutect2, varscan2
- MGAM | c.4618+3215C>T | Intron (SNP) | VAF 36/102 reads (35%) | catalogued as rs751133007, COSV101527548; called by muse, mutect2, varscan2
- MIR543 | n.14G>C | RNA (SNP) | VAF 17/68 reads (25%) | catalogued as rs1403250713; called by muse, mutect2, varscan2
- SNORD113-6 | n.22G>T | RNA (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- SSPOP | n.14449C>T | RNA (SNP) | VAF 36/146 reads (25%) | catalogued as COSV100948045; called by muse, mutect2, varscan2
- SSX6P | n.170G>T | RNA (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- TP73-AS1 | n.1551G>T | RNA (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1327A>T | 3'UTR (SNP) | VAF 41/118 reads (35%) | catalogued as COSV99747453; called by muse, mutect2, varscan2
